CCDI case PBCJWK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/408db991-99c4-4f3d-9607-9bba3dbdbc31

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 2.0 years (722 days).

Biospecimens (2 samples)
- Sample 0DTUI1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTUIJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
